Somatic mutation profile of tumor specimen TCGA-AZ-4681-01A (aliquot TCGA-AZ-4681-01A-01D-1408-10) from TCGA case TCGA-AZ-4681, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.1 years (28,906 days).
Specimen TCGA-AZ-4681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c50b1d1b-233e-4f65-b466-3f00debc10b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4681-10A (Blood Derived Normal), aliquot TCGA-AZ-4681-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c900027-11b8-470f-88a4-8ed41149df2f

The open-access MAF lists 86 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Frame Shift Ins 5, Nonsense Mutation 3, In Frame Del 1, In Frame Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 39/49 reads (80%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 36/67 reads (54%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1554570706, CM066809, COSV58343389; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 30/38 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAD2 | c.1426G>A p.E476K (on ENST00000315906 / NM_001145400.2; = p.E558K on NM_139174.4) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs754189973, COSV51893826; called by muse, mutect2, varscan2
- AMBP | c.438T>G p.I146M | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as COSV54325423; called by muse, mutect2, varscan2
- BCORL1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1403214128, COSV99500222; called by muse, mutect2, varscan2
- CALD1 | c.683T>A p.L228* | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | catalogued as COSV100724426, COSV62652835; called by muse, mutect2
- CDH18 | c.1480A>G p.I494V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56956798; called by muse, mutect2, varscan2
- CHRNE | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.54); PolyPhen benign (0.055); catalogued as COSV99545151; called by muse, mutect2, varscan2
- CREB5 | c.1043A>G p.Q348R (on ENST00000357727 / NM_182898.4; = p.Q341R on NM_004904.3) | Missense Mutation (SNP) | VAF 116/198 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV100745078; called by muse, mutect2, varscan2
- CSRNP3 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100086079; called by muse, mutect2, varscan2
- CUEDC1 | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64227187; called by muse, mutect2, varscan2
- DLG3 | c.2095G>A p.D699N (on ENST00000374360 / NM_021120.4; = p.D394N on NM_020730.3) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.898); catalogued as COSV52086402; called by muse, mutect2, varscan2
- DMD | c.4804G>A p.G1602R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs1194595135, COSV63787842; called by muse, mutect2, varscan2
- DNAH10 | c.1967T>C p.I656T (on ENST00000409039; = p.I595T on NM_207437.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs766899778, COSV101292455; called by muse, mutect2, varscan2
- DUSP3 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs200022065, COSV56824919; called by muse, mutect2, varscan2
- ERICH3 | c.3799G>A p.V1267M | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs757559200, COSV100443380, COSV58616922; called by muse, mutect2, varscan2
- FAM71A | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs201411958, COSV54238031; called by muse, mutect2, varscan2
- FANCM | c.4041G>T p.L1347F | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.08); catalogued as COSV99951336; called by muse, mutect2
- FAT2 | c.9469G>A p.E3157K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as rs770443495, COSV55819709; called by muse, mutect2
- FCHO2 | c.404C>A p.A135D | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as COSV55111300; called by muse, mutect2, varscan2
- FGFR2 | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV100336784; called by muse, mutect2
- GRIA1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as rs538018115, COSV53605357, COSV53628376; called by muse, mutect2, varscan2
- GYS2 | c.604T>C p.F202L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99680046; called by muse, mutect2, varscan2
- HK3 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs772190732, COSV52837118; called by muse, mutect2, varscan2
- HOXC4 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324171; called by muse, mutect2, varscan2
- IMPDH1 | c.403C>T p.R135W (on ENST00000470772 / NM_001142573.2; = p.R221W on NM_000883.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs771930753, COSV58318042; called by muse, mutect2, varscan2
- IRF2BP2 | c.1395C>G p.N465K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as COSV100784358; called by muse, varscan2
- KCNT2 | c.3278T>G p.I1093R | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99655358; called by muse, mutect2
- KLHL34 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1426612106, COSV65279903; called by muse, mutect2
- KRT85 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs766037993, COSV57738797; called by muse, mutect2, varscan2
- MAP3K5 | c.3613C>G p.Q1205E | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100753061; called by muse, mutect2, varscan2
- MARK1 | c.1529C>A p.T510N | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100857392; called by muse, mutect2, varscan2
- MSH2 | c.2396A>G p.N799S | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99254284; called by muse, mutect2, varscan2
- MUC17 | c.6493A>T p.S2165C | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV100074303; called by muse, varscan2
- MUC6 | c.4508C>T p.T1503M | Missense Mutation (SNP) | VAF 170/433 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1419321513, COSV70149560; called by mutect2, varscan2
- MYORG | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52628268; called by muse, mutect2, varscan2
- NUP133 | c.2306G>A p.S769N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99773217; called by muse, mutect2, varscan2
- NYAP2 | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs749778663, COSV56008461; called by muse, mutect2, varscan2
- OSBPL10 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV101159672; called by muse, mutect2, varscan2
- PCDHA5 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as rs886912020, COSV65360273; called by muse, mutect2, varscan2
- PDE5A | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99308960; called by muse, mutect2
- PDZRN4 | c.2800G>A p.E934K (on ENST00000402685 / NM_001164595.2; = p.E676K on NM_013377.4) | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54199851; called by muse, mutect2, varscan2
- PPP1R10 | c.829A>C p.K277Q | Missense Mutation (SNP) | VAF 109/234 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100919905; called by muse, mutect2, varscan2
- PRSS12 | c.2347_2349del p.Q783del | In Frame Del (DEL) | VAF 43/123 reads (35%) | catalogued as rs1260648705; called by pindel, varscan2
- PSD | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs755558509, COSV99193037; called by muse, mutect2, varscan2
- PTCH1 | c.3539C>A p.P1180Q | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59492272; called by muse, mutect2
- RET | c.2851C>G p.P951A | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394081, COSV100394197; called by muse, mutect2, varscan2
- RTL9 | c.1867G>A p.A623T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV101511744; called by muse, mutect2, varscan2
- SAMD9L | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs746667481, COSV100560951; called by muse, mutect2, varscan2
- SCN7A | c.741dup p.L248Sfs*19 | Frame Shift Ins (INS) | VAF 10/102 reads (10%) | catalogued as rs769551067; called by mutect2, pindel
- SLC35F3 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.155); catalogued as COSV100785437; called by muse, mutect2, varscan2
- SMG9 | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99526847; called by muse, mutect2, varscan2
- STRA8 | c.258+1G>C p.X86_splice (on ENST00000275764; = p.X64_splice on NM_182489.2) | Splice Site (SNP) | VAF 32/125 reads (26%) | catalogued as COSV99312548; called by muse, mutect2, varscan2
- THRB | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99769642; called by muse, mutect2, varscan2
- TMEM25 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782282864, COSV100244842; called by muse, mutect2
- TRIP10 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.921); catalogued as COSV99901448; called by muse, mutect2, varscan2
- TRMT1L | c.1415C>A p.P472H | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100834686; called by muse, varscan2
- TTBK1 | c.2893G>T p.A965S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV52496064; called by muse, mutect2, varscan2
- ZGPAT | c.1139C>G p.T380S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100203221; called by muse, mutect2, varscan2
- ZKSCAN7 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV99837685; called by muse, mutect2, varscan2
- CXCL16 | c.157_158insG p.Q53Rfs*46 | Frame Shift Ins (INS) | VAF 20/28 reads (71%) | called by mutect2, pindel*, varscan2
- PRRC2A | c.2419dup p.T807Nfs*10 | Frame Shift Ins (INS) | VAF 22/52 reads (42%) | called by mutect2, pindel, varscan2
- RGMB | c.311_313dup p.V104_Y105insL (on ENST00000513185 / NM_001366508.1; = p.V145_Y146insL on NM_001012761.3 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 31/38 reads (82%) | called by mutect2, pindel, varscan2
- SOX9 | c.768dup p.R257Afs*39 | Frame Shift Ins (INS) | VAF 63/150 reads (42%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.478_484dup p.F162Sfs*314 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, varscan2
- AC092143.1 | c.1521C>T p.P507= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs1479959389, COSV59248974; called by muse, mutect2, varscan2
- CADM3 | c.615G>A p.A205= (on ENST00000368125 / NM_001127173.3; = p.A239= on NM_021189.5) | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs367893559; called by muse, mutect2, varscan2
- CARD14 | c.2640C>T p.S880= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs367654497; called by muse, mutect2, varscan2
- CNNM4 | c.1659C>T p.A553= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs763026644, COSV65662028; called by muse, mutect2, varscan2
- DNAJC13 | c.6108C>T p.S2036= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1292315204, COSV99607690; called by muse, mutect2, varscan2
- DOCK2 | c.1809C>T p.S603= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs749704247, COSV99913979; called by muse, mutect2, varscan2
- DPP6 | c.1182C>T p.V394= (on ENST00000377770 / NM_001364500.2; = p.V332= on NM_001936.5) | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as rs757195104, COSV100126863, COSV59602578; called by muse, mutect2, varscan2
- FRG2C | c.42C>T p.S14= | Silent (SNP) | VAF 65/291 reads (22%) | catalogued as rs1279474147; called by muse, mutect2, varscan2
- H3C4 | c.270G>T p.V90= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as COSV100587228, COSV61911689; called by muse, mutect2, varscan2
- LGR6 | c.510C>T p.D170= (on ENST00000367278 / NM_001017403.1; = p.D118= on NM_021636.3) | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs373499034; called by muse, mutect2, varscan2
- NAV3 | c.2136C>A p.T712= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV57071432, COSV99893444; called by muse, mutect2, varscan2
- PEX1 | c.897C>T p.N299= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as rs559305030, COSV50394831; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC38A8 | c.426G>A p.P142= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs201965163, COSV55304247; called by muse, mutect2, varscan2
- SUGCT | c.1056C>A p.I352= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV59350990; called by muse, mutect2, varscan2
- SYNE1 | c.2478C>A p.S826= (on ENST00000367255 / NM_182961.4; = p.S833= on NM_033071.3) | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs752337342, COSV55012332; called by muse, mutect2, varscan2
- TTN | c.64122G>A p.A21374= (on ENST00000591111; = p.A13950= on NM_003319.4) | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as rs759122929, COSV60010289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA1A | c.390G>A p.T130= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as rs1143559, COSV99853772; called by muse, mutect2, varscan2
- ZNF484 | c.2415G>A p.K805= | Silent (SNP) | VAF 72/173 reads (42%) | catalogued as COSV100214779; called by muse, mutect2, varscan2
- DNM1P46 | n.983T>C | RNA (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2
